Somatic mutation profile of tumor specimen TCGA-06-0171-01A (aliquot TCGA-06-0171-01A-02D-1491-08) from TCGA case TCGA-06-0171, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.9 years (24,085 days).
Specimen TCGA-06-0171-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca020c97-964e-4839-95e8-9a482ddea495.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0171-10A (Blood Derived Normal), aliquot TCGA-06-0171-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/550e98a3-df48-47a7-8e28-d652ba87f796

The open-access MAF lists 51 somatic variants for this specimen: 41 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 2, Splice Site 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 45/126 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKAP13 | c.342C>A p.N114K | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63449105; called by muse, mutect2, varscan2
- COL6A3 | c.7475C>T p.S2492L | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754480145, COSV55079530; ClinVar: uncertain significance; called by muse, varscan2
- COL6A6 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756106307, COSV62016664, COSV62040144; called by muse, mutect2, varscan2
- CSPG4 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756062229, COSV57890072; called by muse, mutect2, varscan2
- CYP4F11 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201156268, COSV56125672; called by muse, mutect2
- DNAH5 | c.9644A>T p.E3215V | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV54205282; called by muse, mutect2
- DSC2 | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV51861030; called by muse, mutect2, varscan2
- FST | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as COSV56814930; called by muse, mutect2
- GPR15 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52520075; called by muse, mutect2
- HFM1 | c.2659C>T p.H887Y | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV54021524; called by muse, mutect2, varscan2
- HLTF | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as COSV59498743; called by muse, mutect2, varscan2
- KCNH1 | c.1222G>A p.E408K (on ENST00000271751 / NM_172362.3; = p.E381K on NM_002238.4) | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.065); catalogued as rs773231948, COSV55069391, COSV55081940; called by muse, mutect2, varscan2
- KHSRP | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67919249, COSV67919360; called by muse, mutect2, varscan2
- LILRB4 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV54403569; called by muse, mutect2
- MAMDC4 | c.2526G>A p.W842* (on ENST00000445819; = p.W763* on NM_206920.3) | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | catalogued as COSV56374952; called by muse, mutect2, varscan2
- MDC1 | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 184/633 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV64523133; called by muse, mutect2, varscan2
- MTHFR | c.1928del p.L643Pfs*19 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | catalogued as COSV57171285; called by mutect2, pindel, varscan2
- NOS3 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768430429, COSV52486177; called by muse, mutect2, varscan2
- ONECUT2 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs769761027, COSV72152960; called by muse, mutect2, varscan2
- PCMTD1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs748890802, COSV62119669; called by muse, mutect2, varscan2
- PKHD1 | c.5965C>T p.L1989F | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61860124; called by muse, mutect2, varscan2
- POTED | c.384C>A p.F128L | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV55046523; called by muse, mutect2, varscan2
- PPP3R2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569559919, COSV62450543; called by muse, mutect2, varscan2
- PXK | c.1181+1G>A p.X394_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as rs1213871054, COSV57086762; called by muse, mutect2, varscan2
- RBM47 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as rs776189003, COSV55930008; called by muse, mutect2, varscan2
- RBPJL | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.564); catalogued as COSV59212775; called by muse, mutect2, varscan2
- RIMS2 | c.2960G>A p.R987H (on ENST00000666250 / NM_001348490.2; = p.R795H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV51655098; called by muse, mutect2, varscan2
- RNF168 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58836695; called by muse, mutect2, varscan2
- RPTOR | c.3940-2A>G p.X1314_splice | Splice Site (SNP) | VAF 31/115 reads (27%) | catalogued as COSV60803038; called by muse, mutect2, varscan2
- SLC4A7 | c.3622G>A p.V1208M | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as rs200768562, COSV55394801; called by muse, mutect2, varscan2
- SOHLH1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs774707931, COSV53680423; called by muse, mutect2, varscan2
- TCF21 | c.74T>C p.M25T | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs775850686, COSV52817660; called by muse, varscan2
- TRIM24 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs770786278, COSV58968920; called by muse, mutect2, varscan2
- TRIML2 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 129/403 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV58714539; called by muse, mutect2, varscan2
- TRPV6 | c.1242G>T p.Q414H | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV63890447; called by muse, mutect2, varscan2
- ZNF407 | c.6046G>A p.A2016T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs546961134, COSV55242402; called by muse, mutect2, varscan2
- CFAP65 | c.4782_4784del p.P1595del | In Frame Del (DEL) | VAF 38/150 reads (25%) | called by mutect2, pindel, varscan2
- IGHV3-43 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- TNIP1 | c.1104_1106del p.L369del | In Frame Del (DEL) | VAF 27/132 reads (20%) | called by pindel, varscan2
- TTN | c.33121del p.V11041Ffs*81 (on ENST00000591111; = p.V10114Ffs*81 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 72/279 reads (26%) | called by mutect2, pindel, varscan2
- CAMK2A | c.1152C>T p.A384= (on ENST00000348628 / NM_171825.2; = p.A395= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV62245016; called by muse, mutect2, varscan2
- DNAH5 | c.11970T>C p.S3990= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV54203522; called by muse, mutect2, varscan2
- FAM98A | c.498A>G p.Q166= | Silent (SNP) | VAF 109/341 reads (32%) | catalogued as rs561820764, COSV53208861; called by muse, mutect2, varscan2
- INPP5K | c.54C>T p.V18= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs752181436, COSV57439847, COSV57441312; called by muse, mutect2, varscan2
- KRTAP13-1 | c.429C>T p.G143= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs565845316, COSV62662638; called by muse, mutect2, varscan2
- SAMD3 | c.597C>T p.D199= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs768298745, COSV60774019, COSV60776122; called by muse, mutect2, varscan2
- SPRR4 | c.210C>T p.A70= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV60142553; called by muse, mutect2, varscan2
- ZNF98 | c.666C>G p.A222= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV63334322, COSV63336247; called by muse, mutect2, varscan2
- FAM169B | n.265G>A | RNA (SNP) | VAF 17/53 reads (32%) | catalogued as rs762037007, COSV60567917; called by muse, mutect2, varscan2
- WNK2 | c.*17C>T | 3'UTR (SNP) | VAF 39/127 reads (31%) | catalogued as rs372704041; called by muse, mutect2, varscan2
